Gene-level copy-number profile of tumor specimen TCGA-HJ-7597-01A from TCGA case TCGA-HJ-7597, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 71.9 years (26,264 days).
Specimen TCGA-HJ-7597-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.47291166-59b1-4afc-aac1-303e70280854.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HJ-7597-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1001d598-95e0-46b2-89e3-07a532df9c0c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 2,887; copy number 2: 54,192; copy number 3: 2,726.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HJ-7597-01A-21D-2200-01): tumor purity 0.42, ploidy 3.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:36,968,191–37,244,177, 15 genes: RNU6ATAC4P, AC011816.2, PRADC1P1, EPM2AIP1, MLH1, RPL29P11, LRRFIP2, Y_RNA, UBE2D3P2, RNU6-1301P, UBE2FP1, AC126118.1, AC097359.1, AC097359.3, AC097359.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,887. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
